Somatic mutation profile of tumor specimen TCGA-CG-4460-01A (aliquot TCGA-CG-4460-01A-01D-1158-08) from TCGA case TCGA-CG-4460, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 66.3 years (24,229 days).
Specimen TCGA-CG-4460-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7bf8d827-c5d2-4baa-83ea-3ac8e2c86c1e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-4460-10A (Blood Derived Normal), aliquot TCGA-CG-4460-10A-01D-1158-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da179c30-1230-4707-9c50-8ee9e4b81890

The open-access MAF lists 2,175 somatic variants for this specimen: 1,617 protein-altering or splice-affecting, 514 silent, 44 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,170, Silent 514, Frame Shift Del 270, Nonsense Mutation 70, Frame Shift Ins 64, Intron 21, Splice Site 16, Splice Region 16, In Frame Del 10, RNA 10, 3'Flank 5, 3'UTR 4.

Variants (750 of 2,175; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPM | c.5149del p.I1717* | Frame Shift Del (DEL) | VAF 221/432 reads (51%) | catalogued as rs199422167, CD077387; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BRCA2 | c.9097del p.T3033Lfs*29 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs397507419; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- CENPF | c.5920del p.T1974Pfs*11 | Frame Shift Del (DEL) | VAF 24/176 reads (14%) | catalogued as rs757531591; ClinVar: pathogenic; called by mutect2, varscan2
- GLB1 | c.1768C>T p.R590C | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs794727165, CM064027, CM1210297, COSV100256832; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNAS | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 44/132 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs121913495, CM158823, COSV55670349, COSV55671845; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MFRP | c.3del p.H2Tfs*100 (on ENST00000449574; = p.H384Tfs*94 on NM_031433.4) | Frame Shift Del (DEL) | VAF 10/21 reads (48%) | catalogued as rs587776595; ClinVar: pathogenic; called by mutect2, varscan2
- MSH6 | c.3312del p.F1104Lfs*11 | Frame Shift Del (DEL) | VAF 24/117 reads (21%) | catalogued as rs267608092; ClinVar: not provided / pathogenic; called by mutect2, pindel, varscan2
- MTHFR | c.379C>T p.H127Y | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769381688, CM155515, COSV100412283; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 12/16 reads (75%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- MYOC | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 29/256 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs74315330, CM971024, COSV50674332; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NDE1 | c.733del p.L245Sfs*26 (on ENST00000577101; = p.L245Sfs*113 on NM_017668.3) | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | catalogued as rs749768828; ClinVar: pathogenic; called by pindel, varscan2
- PAH | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs5030843, CM015340, CM890093; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RB1 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 49/111 reads (44%) | hotspot (GDC flag); catalogued as rs1131690863, CM941204, COSV57294817; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SACS | c.8793del p.K2931Nfs*22 | Frame Shift Del (DEL) | VAF 23/151 reads (15%) | catalogued as rs767871841, CD056854; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- SF3B4 | c.1147del p.H383Mfs*75 | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | catalogued as rs387907186, CD123383; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 10/42 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2
- A4GNT | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267599622, COSV52628852; called by muse, mutect2, varscan2
- ABCB10 | c.1467G>T p.Q489H | Missense Mutation (SNP) | VAF 50/464 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs750438122, COSV60620072; called by muse, mutect2, varscan2
- ABCB11 | c.1847G>A p.R616H | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777021400, CM166694, COSV99793452; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB5 | c.3475G>A p.G1159S (on ENST00000404938 / NM_001163941.2; = p.G714S on NM_178559.6) | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs142824450; called by muse, mutect2, varscan2
- ABCB8 | c.1376G>T p.G459V (on ENST00000297504 / NM_001282291.2; = p.G442V on NM_007188.5) | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as COSV99875233; called by muse, mutect2, varscan2
- ABCC11 | c.2217G>A p.S739= | Splice Region (SNP) | VAF 56/153 reads (37%) | catalogued as rs779237531, COSV100751264; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs749943218; called by mutect2, varscan2
- ABCF1 | c.887C>T p.A296V (on ENST00000326195 / NM_001025091.2; = p.A258V on NM_001090.3) | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.173); catalogued as COSV100401154; called by muse, mutect2, varscan2
- ABCG1 | c.1750G>A p.V584I | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.969); catalogued as rs977728671, COSV100494581; called by muse, varscan2
- ABCG5 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756734792, COSV99575586; called by muse, mutect2, varscan2
- AC090517.4 | c.1783del p.S595Vfs*7 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | catalogued as rs1157171684; called by mutect2, pindel, varscan2
- ACACA | c.2636C>T p.T879M | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.481); catalogued as rs764378176; called by muse, mutect2, varscan2
- ACAN | c.7067A>T p.E2356V (on ENST00000560601 / NM_001369268.1; = p.E2280V on NM_001135.3) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100719463; called by muse, mutect2, varscan2
- ACHE | c.806C>T p.T269M | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs775312669, COSV53821463; called by muse, mutect2, varscan2
- ACOT12 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.841); catalogued as rs199607014, COSV56896698; called by muse, mutect2, varscan2
- ACSL4 | c.1771G>A p.A591T (on ENST00000340800 / NM_022977.2; = p.A550T on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/106 reads (62%) | SIFT tolerated (0.29); PolyPhen benign (0.34); catalogued as COSV100539184; called by muse, mutect2, varscan2
- ACTN2 | c.1295C>T p.A432V | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as rs767291633, COSV100857121; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTR1B | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.39); catalogued as rs565812380, COSV56703875; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 60/206 reads (29%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM15 | c.2170C>T p.R724* | Nonsense Mutation (SNP) | VAF 44/71 reads (62%) | catalogued as rs142428973; called by muse, mutect2, varscan2
- ADAM30 | c.844del p.S282Vfs*3 | Frame Shift Del (DEL) | VAF 18/84 reads (21%) | catalogued as rs757984494, COSV65561192; called by mutect2, pindel, varscan2
- ADAMDEC1 | c.930C>T p.S310= | Splice Region (SNP) | VAF 66/192 reads (34%) | catalogued as rs770119001, COSV56474499; called by muse, mutect2, varscan2
- ADAMTS12 | c.4687G>A p.V1563M | Missense Mutation (SNP) | VAF 219/334 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as rs952508108, COSV100711804; called by muse, mutect2, varscan2
- ADAMTS14 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.611); catalogued as rs202183313; called by muse, mutect2, varscan2
- ADAMTS3 | c.254C>T p.T85M | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs763301017, COSV99712429; called by muse, mutect2, varscan2
- ADAMTS5 | c.2083A>C p.N695H | Missense Mutation (SNP) | VAF 54/251 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV99538528; called by muse, mutect2, varscan2
- ADAMTS9 | c.3955G>A p.A1319T | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs778701337, COSV99900458; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4123dup p.Q1375Pfs*53 | Frame Shift Ins (INS) | VAF 26/80 reads (33%) | catalogued as rs758913277; called by mutect2, varscan2
- ADCY5 | c.2488T>C p.S830P | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV100568400; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.13G>A p.V5M | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs759359114, COSV58448939; called by muse, mutect2, varscan2
- ADGRF5 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs138516675; called by muse, mutect2, varscan2
- ADGRG3 | c.1027dup p.A343Gfs*17 | Frame Shift Ins (INS) | VAF 32/212 reads (15%) | catalogued as rs764828465; called by mutect2, pindel, varscan2
- ADGRV1 | c.3310T>C p.Y1104H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV101316701; called by muse, mutect2
- ADH1C | c.1114G>A p.V372I | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs370818269; called by muse, mutect2, varscan2
- ADPRM | c.410A>G p.H137R | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV101126120; called by muse, mutect2, varscan2
- ADRA1A | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 69/182 reads (38%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs567016649, COSV99372687; called by muse, mutect2, varscan2
- ADRA2B | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as COSV69787692; called by muse, mutect2, varscan2
- AGAP1 | c.2213G>A p.R738Q (on ENST00000304032 / NM_001037131.3; = p.R685Q on NM_014914.5) | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.056); catalogued as rs534251010, COSV58329354; called by muse, mutect2, varscan2
- AGBL2 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 59/98 reads (60%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs745526604, COSV54089752; called by muse, mutect2, varscan2
- AGO2 | c.1870C>T p.R624C | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1196970558, COSV99596626; called by muse, mutect2
- AHNAK | c.9037G>A p.V3013I | Missense Mutation (SNP) | VAF 62/363 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0.382); catalogued as rs759980251, COSV57215824; called by muse, mutect2, varscan2
- AHNAK | c.613G>A p.V205M | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as rs994476432, COSV99948683; called by muse, mutect2, varscan2
- AIMP2 | c.710T>C p.V237A | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV99552463; called by muse, mutect2, varscan2
- AKAP8L | c.1364G>A p.G455D | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV101275905; called by muse, mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | catalogued as COSV62339755; called by mutect2, varscan2
- AKNAD1 | c.2256del p.K752Nfs*6 | Frame Shift Del (DEL) | VAF 5/45 reads (11%) | catalogued as rs757405671; called by mutect2, pindel, varscan2
- AL031777.2 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 33/305 reads (11%) | catalogued as rs745520217, COSV100587307; called by muse, mutect2, varscan2
- ALDH8A1 | c.1166C>T p.T389M | Missense Mutation (SNP) | VAF 83/163 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs747404906, COSV55642213; called by muse, mutect2, varscan2
- ALMS1 | c.12226C>T p.R4076W | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368113488; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALOX15 | c.1715C>T p.T572M | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761098208, COSV99541831; called by muse, mutect2, varscan2
- ALPK2 | c.2644G>A p.G882S | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs574202609, COSV100864274, COSV100864948; called by muse, mutect2, varscan2
- ALPK3 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs574988897, COSV51929582; called by muse, varscan2
- ALPK3 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99362206; called by muse, varscan2
- AMDHD2 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs779695777, COSV99566278; called by muse, mutect2, varscan2
- AMER1 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs759613339, COSV100367201; called by muse, mutect2, varscan2
- AMER2 | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.262); catalogued as rs773634447, COSV100766432; called by muse, mutect2, varscan2
- AMMECR1L | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.091); catalogued as rs751255093, COSV99761632; called by muse, mutect2, varscan2
- ANGPTL1 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 37/322 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs183060436, COSV99328443; called by muse, mutect2, varscan2
- ANGPTL2 | c.253C>T p.H85Y | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.105); catalogued as COSV99402845; called by muse, mutect2, varscan2
- ANKMY1 | c.1546A>G p.M516V | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as COSV99803605; called by muse, mutect2, varscan2
- ANKRD27 | c.2308G>A p.A770T | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.095); catalogued as rs1306229833, COSV100042633; called by muse, mutect2, varscan2
- ANKRD37 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1448574572, COSV99249420; called by muse, varscan2
- ANKRD52 | c.2252A>G p.D751G | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99921690; called by muse, mutect2, varscan2
- ANO2 | c.2701G>A p.A901T (on ENST00000356134 / NM_001278597.3; = p.A905T on NM_001278596.3) | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs897115855, COSV59046699; called by muse, mutect2, varscan2
- ANO6 | c.2495C>T p.A832V | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV100264136; called by muse, mutect2, varscan2
- ANXA2R | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.09); catalogued as COSV100148745; called by muse, mutect2, varscan2
- AOC3 | c.1208A>G p.D403G | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99520507; called by muse, mutect2, varscan2
- AP1M1 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377502937; called by muse, mutect2, varscan2
- AP2M1 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 137/235 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as rs1174158560, COSV53049965; called by muse, mutect2, varscan2
- APOA5 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs756286096, COSV99911554; called by muse, mutect2, varscan2
- APOBEC3B | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs747995529, COSV59840816; called by muse, mutect2, varscan2
- AQP10 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 76/615 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100270579; called by muse, mutect2, varscan2
- AQP10 | c.773C>A p.A258D | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.305); catalogued as COSV100270583; called by muse, mutect2, varscan2
- ARCN1 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as rs782690322, COSV50616581; called by muse, mutect2, varscan2
- ARFGEF1 | c.2864C>A p.P955H | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99145617; called by muse, mutect2
- ARHGAP30 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 30/264 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs371385714; called by muse, mutect2, varscan2
- ARHGAP9 | c.1790G>A p.R597H (on ENST00000393797 / NM_001319850.2; = p.R578H on NM_032496.4) | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376421872; called by muse, mutect2, varscan2
- ARHGEF10 | c.1993C>T p.R665* (on ENST00000398564; = p.R640* on NM_014629.4) | Nonsense Mutation (SNP) | VAF 55/218 reads (25%) | catalogued as rs138007359, COSV100033682; called by muse, mutect2, varscan2
- ARHGEF17 | c.1418C>T p.T473M | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as rs1047609049, COSV99735760; called by muse, mutect2, varscan2
- ARHGEF19 | c.2335G>A p.A779T | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs774766550, COSV99580287; called by muse, mutect2, varscan2
- ARHGEF7 | c.1888G>A p.G630S (on ENST00000375741 / NM_001113511.2; = p.G452S on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.988); catalogued as COSV99522327; called by muse, mutect2, varscan2
- ARID4B | c.988C>T p.R330* | Nonsense Mutation (SNP) | VAF 6/69 reads (9%) | catalogued as COSV51607689; called by muse, mutect2
- ARL5A | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1452947636, COSV99706861; called by muse, mutect2
- ARMC1 | c.692T>C p.V231A | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs546386774, COSV99395225; called by muse, mutect2, varscan2
- ARMC5 | c.119T>C p.L40P | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs775592992, COSV99192926; called by muse, mutect2, varscan2
- ARRB2 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 90/276 reads (33%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.926); catalogued as COSV52617137; called by muse, varscan2
- ARSB | c.1588G>A p.G530S | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.047); catalogued as COSV99365694; called by muse, mutect2, varscan2
- ASB1 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs143803285; called by muse, mutect2, varscan2
- ASCC3 | c.4882C>T p.R1628* | Nonsense Mutation (SNP) | VAF 15/62 reads (24%) | catalogued as COSV100977078; called by muse, mutect2, varscan2
- ASCL3 | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 58/93 reads (62%) | catalogued as COSV100366958; called by muse, mutect2, varscan2
- ASPM | c.3493A>G p.T1165A | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557955789, COSV99661345; called by muse, mutect2, varscan2
- ASTE1 | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.092); catalogued as rs768795298, COSV53908238; called by muse, mutect2, varscan2
- ASXL1 | c.2419G>A p.V807I | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs138624526; ClinVar: likely benign; called by muse, mutect2, varscan2
- ASXL1 | c.3203G>A p.R1068Q | Missense Mutation (SNP) | VAF 79/224 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as rs752058283, COSV60108649; called by muse, mutect2, varscan2
- ATAD2 | c.3426G>C p.E1142D | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99785526; called by muse, mutect2, varscan2
- ATAD3B | c.598C>T p.R200W (on ENST00000308647; = p.R306W on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs759930254, COSV100426689; called by muse, mutect2, varscan2
- ATF4 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1429272758, COSV100307882; called by muse, mutect2, varscan2
- ATF5 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756468104, COSV61313288; called by muse, mutect2, varscan2
- ATF6 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 79/652 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100909577; called by muse, mutect2, varscan2
- ATF7IP | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 15/66 reads (23%) | catalogued as COSV53766527; called by muse, mutect2, varscan2
- ATN1 | c.764del p.P255Hfs*43 | Frame Shift Del (DEL) | VAF 15/84 reads (18%) | catalogued as rs1555143544, COSV63112070; called by mutect2, pindel, varscan2
- ATN1 | c.1275del p.K426Sfs*27 | Frame Shift Del (DEL) | VAF 198/410 reads (48%) | catalogued as rs782523332; called by mutect2, pindel, varscan2
- ATP10B | c.3092C>T p.T1031M | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373180683; called by muse, mutect2, varscan2
- ATP13A5 | c.2618C>G p.S873C | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100665680, COSV100665895; called by muse, mutect2, varscan2
- ATP1A1 | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as rs768375815, COSV55193559; called by muse, mutect2, varscan2
- ATP2A2 | c.632G>A p.G211D | Missense Mutation (SNP) | VAF 54/382 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM164206, CM990233, COSV100429012; called by muse, mutect2, varscan2
- ATP2B2 | c.1594G>A p.A532T (on ENST00000352432; = p.A498T on NM_001683.5) | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.572); catalogued as rs777396418, COSV59489637; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP5F1B | c.1385G>A p.R462H | Missense Mutation (SNP) | VAF 71/173 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as rs766490903, COSV99468134; called by muse, mutect2, varscan2
- ATP5MC3 | c.314+2T>C p.X105_splice | Splice Site (SNP) | VAF 9/52 reads (17%) | catalogued as COSV52976290, COSV99507279; called by muse, mutect2, varscan2
- ATP6V1A | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99850476; called by muse, mutect2, varscan2
- ATP6V1G3 | c.116A>G p.E39G | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99811131; called by muse, varscan2
- ATP9A | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs1273614407, COSV100125771; called by muse, mutect2, varscan2
- ATXN2 | c.1841G>A p.R614H (on ENST00000550104; = p.R454H on NM_002973.4) | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs751481895, COSV101112625; called by muse, mutect2, varscan2
- ATXN2L | c.2997del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 45/174 reads (26%) | catalogued as rs1288664341; called by mutect2, pindel, varscan2
- AUTS2 | c.3449A>T p.D1150V | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100719793; called by muse, mutect2, varscan2
- AVPR1A | c.1192A>G p.T398A | Missense Mutation (SNP) | VAF 82/238 reads (34%) | SIFT tolerated (0.95); PolyPhen benign (0.101); catalogued as COSV100146850; called by muse, mutect2, varscan2
- AXIN2 | c.1984C>A p.L662M | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.789); catalogued as COSV100197102, COSV61060034; called by muse, mutect2, varscan2
- B3GAT1 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV56997599; called by muse, mutect2, varscan2
- BASP1 | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.772); catalogued as rs751498324, COSV100493932; called by muse, varscan2
- BCAR1 | c.2305G>A p.V769M | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757527015, COSV99367661; called by muse, mutect2, varscan2
- BCDIN3D | c.635A>C p.K212T | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100445600; called by muse, mutect2, varscan2
- BCL9 | c.3400C>T p.R1134W | Missense Mutation (SNP) | VAF 49/340 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs782131021, COSV52351357; called by muse, mutect2, varscan2
- BCO2 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs542847943, COSV100730378; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 55/119 reads (46%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BCS1L | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 86/240 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs758643336, COSV55309717; called by muse, mutect2, varscan2
- BFSP1 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs767022516, COSV64899666; called by muse, mutect2, varscan2
- BHMT2 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs778188990, COSV99670344; called by muse, mutect2, varscan2
- BIRC3 | c.470T>C p.L157S | Missense Mutation (SNP) | VAF 74/332 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV99680301; called by muse, mutect2, varscan2
- BLK | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs775270203, COSV99377768; called by muse, mutect2, varscan2
- BLOC1S5 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 123/179 reads (69%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1403788088, COSV55240678; called by muse, mutect2, varscan2
- BMS1 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 111/284 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV100996872; called by muse, mutect2, varscan2
- BNIP2 | c.630T>A p.Y210* | Nonsense Mutation (SNP) | VAF 3/14 reads (21%) | catalogued as COSV99985962; called by muse, mutect2
- BORA | c.360T>A p.F120L (on ENST00000613797; = p.F45L on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100909799; called by muse, mutect2, varscan2
- BPNT2 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 60/207 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1046663; called by muse, mutect2, varscan2
- BRD8 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1420509343, COSV99137900; called by muse, mutect2, varscan2
- BRINP1 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.964); catalogued as rs746081030, COSV56297318; called by muse, mutect2, varscan2
- BRINP3 | c.272T>C p.V91A | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.983); catalogued as rs1176677978, COSV100819595; called by muse, mutect2, varscan2
- BRWD1 | c.1750C>G p.P584A | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100314386; called by muse, mutect2, varscan2
- BSN | c.2195G>A p.R732Q | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as rs376181418, COSV56517028; called by muse, mutect2, varscan2
- BSN | c.3811C>T p.R1271W | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as rs866242564, COSV56526238; called by muse, mutect2, varscan2
- BTBD10 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT tolerated (0.17); PolyPhen benign (0.082); catalogued as rs368074216, COSV53398498; called by muse, mutect2, varscan2
- C10orf67 | c.367C>A p.Q123K (on ENST00000323327; = p.Q124K on NM_153714.3) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.301); catalogued as COSV100033759; called by mutect2, varscan2
- C12orf66 | c.586C>G p.H196D | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.481); catalogued as COSV100320953; called by muse, mutect2, varscan2
- C1QC | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as rs370014774, COSV101009533, COSV101009575; called by muse, mutect2, varscan2
- C1QTNF1 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778176781, COSV100190331; called by muse, mutect2, varscan2
- C2CD2 | c.661G>C p.G221R | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100298498; called by muse, mutect2, varscan2
- C2orf16 | c.501G>T p.L167F | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV101284450; called by muse, mutect2, varscan2
- C3 | c.2012G>A p.R671H | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs1309838043, COSV55569923; called by muse, mutect2, varscan2
- C4orf17 | c.1034A>G p.N345S | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs754085098, COSV99911092; called by muse, mutect2, varscan2
- C7orf25 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1278985739, COSV63273555; called by muse, mutect2, varscan2
- C7orf50 | c.535del p.L179Cfs*136 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | catalogued as rs750339990; called by mutect2, pindel
- C8orf34 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV100448317; called by muse, mutect2, varscan2
- CA6 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.01); catalogued as rs533616544, COSV66262258, COSV66263535; called by muse, varscan2
- CABIN1 | c.4678T>C p.W1560R | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99574251; called by muse, mutect2, varscan2
- CACNA1S | c.2219A>T p.D740V | Missense Mutation (SNP) | VAF 26/313 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as COSV100755473; called by muse, mutect2
- CACNB2 | c.247G>A p.D83N (on ENST00000324631 / NM_201596.3; = p.D28N on NM_000724.4) | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV56626064; called by muse, mutect2, varscan2
- CACNB3 | c.744G>A p.A248= | Splice Region (SNP) | VAF 22/89 reads (25%) | catalogued as rs778175847, COSV99975175; called by muse, mutect2, varscan2
- CACNG5 | c.566C>T p.T189M | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs774198646, COSV50054733; called by muse, mutect2, varscan2
- CADM3 | c.559A>C p.T187P (on ENST00000368125 / NM_001127173.3; = p.T221P on NM_021189.5) | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100930466, COSV63685231; called by muse, mutect2, varscan2
- CALM3 | c.219G>T p.M73I | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV99355341; called by muse, mutect2, varscan2
- CALU | c.248A>G p.D83G | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV99975991; called by muse, mutect2, varscan2
- CAMTA1 | c.4730T>A p.I1577N | Missense Mutation (SNP) | VAF 239/554 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100352869; called by muse, mutect2, varscan2
- CAMTA2 | c.3248G>A p.R1083Q | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1252243327, COSV99236293; called by muse, mutect2, varscan2
- CAPN6 | c.166-1G>A p.X56_splice | Splice Site (SNP) | VAF 27/95 reads (28%) | catalogued as COSV100137161; called by muse, mutect2, varscan2
- CARD9 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1011068857, COSV100261350; called by muse, mutect2, varscan2
- CARHSP1 | c.106G>A p.G36S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as rs2231705, COSV100220299; called by muse, mutect2, varscan2
- CATSPERB | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as rs759202695, COSV99831878; called by muse, mutect2, varscan2
- CATSPERE | c.2222T>C p.L741S | Missense Mutation (SNP) | VAF 91/270 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1348272801, COSV100835434; called by muse, mutect2, varscan2
- CATSPERG | c.3352G>A p.A1118T | Missense Mutation (SNP) | VAF 77/219 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs555054175, COSV99286802; called by muse, mutect2, varscan2
- CAVIN4 | c.348del p.V117Lfs*8 | Frame Shift Del (DEL) | VAF 35/109 reads (32%) | catalogued as COSV100293459, COSV56866986; called by mutect2, pindel, varscan2
- CBFA2T3 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs760316068, COSV51933331; called by muse, mutect2, varscan2
- CBLN3 | c.206del p.P69Lfs*35 | Frame Shift Del (DEL) | VAF 7/38 reads (18%) | catalogued as rs1268177561; called by mutect2, pindel, varscan2
- CCDC178 | c.1729G>A p.A577T | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1323982446, COSV100287497; called by muse, mutect2, varscan2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2
- CCDC73 | c.1913del p.N638Ifs*18 | Frame Shift Del (DEL) | VAF 16/22 reads (73%) | catalogued as rs762553129; called by mutect2, varscan2
- CCDC74B | c.565G>A p.G189S | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs747740384, COSV100134823; called by muse, mutect2, varscan2
- CCNDBP1 | c.796G>T p.G266W | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100281698; called by muse, mutect2, varscan2
- CCNJ | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 86/137 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as rs778391284, COSV99796294; called by muse, mutect2, varscan2
- CCR8 | c.664C>A p.L222M | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100413224; called by muse, mutect2, varscan2
- CD300C | c.223G>T p.A75S | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as COSV100423361; called by muse, mutect2, varscan2
- CD44 | c.873T>G p.S291R | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99556093; called by muse, mutect2, varscan2
- CD80 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 59/121 reads (49%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as rs1391582116, COSV51801372; called by muse, mutect2, varscan2
- CD93 | c.838del p.D280Mfs*19 | Frame Shift Del (DEL) | VAF 34/165 reads (21%) | catalogued as rs1276928429, COSV55666935; called by mutect2, pindel, varscan2
- CDC42BPG | c.3358C>T p.R1120C | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as rs922961975, COSV100712191; called by muse, mutect2, varscan2
- CDC42BPG | c.2219C>T p.S740L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs929436701, COSV100712194; called by muse, varscan2
- CDC7 | c.1369G>T p.D457Y | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV52309692, COSV99320039; called by muse, mutect2, varscan2
- CDCA4 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 39/57 reads (68%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.886); catalogued as rs780223427, COSV60315585; called by muse, mutect2, varscan2
- CDH19 | c.1774G>T p.G592* | Nonsense Mutation (SNP) | VAF 33/113 reads (29%) | catalogued as COSV100052596; called by muse, mutect2, varscan2
- CDH7 | c.2311C>T p.R771* | Nonsense Mutation (SNP) | VAF 32/156 reads (21%) | catalogued as rs1454134664, COSV59896090; called by muse, mutect2, varscan2
- CDK20 | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 47/117 reads (40%) | catalogued as COSV100308320; called by muse, mutect2, varscan2
- CDKAL1 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs764171876, COSV51196644; called by mutect2, varscan2
- CELF5 | c.287G>C p.R96T | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV99486284; called by muse, mutect2, varscan2
- CELSR2 | c.3350T>C p.V1117A | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV99605016; called by muse, mutect2, varscan2
- CELSR2 | c.8435G>A p.R2812Q | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.005); catalogued as rs778529562, COSV54773963; called by muse, mutect2
- CEP57 | c.785del p.K262Rfs*31 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs762013265, COSV57689966; called by mutect2, varscan2
- CEP70 | c.940G>A p.V314I | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs377579375; called by muse, mutect2, varscan2
- CER1 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs752024589, COSV101097948; called by muse, mutect2, varscan2
- CERS3 | c.11C>T p.T4M | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as rs781323689, COSV99433068; called by muse, mutect2, varscan2
- CERS6 | c.738G>T p.E246D | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99988041; called by muse, mutect2, varscan2
- CFAP70 | c.2083G>T p.A695S | Missense Mutation (SNP) | VAF 77/248 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV100161175; called by muse, mutect2, varscan2
- CFAP97 | c.306del p.K102Nfs*23 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as rs1305639008; called by mutect2, pindel, varscan2
- CFH | c.1700G>T p.R567I | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as COSV100810382; called by muse, mutect2
- CGN | c.2176C>T p.R726W | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs369495663; called by muse, mutect2, varscan2
- CHAMP1 | c.1928C>T p.A643V | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs782149634, COSV63522582; called by muse, mutect2, varscan2
- CHD2 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 55/116 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1041959719, COSV100560491; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD4 | c.1319G>A p.R440Q (on ENST00000357008 / NM_001363606.2; = p.R453Q on NM_001273.5) | Missense Mutation (SNP) | VAF 130/489 reads (27%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.986); catalogued as COSV100539528; called by muse, mutect2, varscan2
- CHD7 | c.4895G>A p.R1632H | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as rs775776506, COSV101418603; called by muse, mutect2, varscan2
- CHL1 | c.218G>A p.G73D | Missense Mutation (SNP) | VAF 75/171 reads (44%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.687); catalogued as rs776135946, COSV99852739; called by muse, mutect2, varscan2
- CHN1 | c.361T>G p.L121V | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101303572; called by muse, mutect2, varscan2
- CHRM5 | c.28A>G p.T10A | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV101272081; called by muse, mutect2, varscan2
- CHTF18 | c.2900G>A p.R967H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs375692944; called by mutect2, varscan2
- CIT | c.3835C>A p.L1279I | Missense Mutation (SNP) | VAF 65/164 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV99951420; called by muse, mutect2, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 22/52 reads (42%) | catalogued as rs752250702; called by mutect2, varscan2
- CKB | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV100818978; called by muse, mutect2, varscan2
- CLDN6 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374481726, COSV100172117; called by muse, mutect2, varscan2
- CLEC14A | c.1148C>T p.T383M | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100643697; called by muse, mutect2, varscan2
- CLIP3 | c.920C>T p.T307M | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.346); catalogued as rs552087785, COSV100859380; called by muse, mutect2
- CLK2 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 43/225 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); catalogued as rs201854491, COSV62877308; called by muse, mutect2, varscan2
- CMIP | c.688G>A p.A230T (on ENST00000537098 / NM_198390.2; = p.A136T on NM_030629.3) | Missense Mutation (SNP) | VAF 199/599 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as rs1381906760, COSV67699213; called by muse, mutect2, varscan2
- CMKLR1 | c.845T>C p.L282P (on ENST00000312143 / NM_001142344.2; = p.L280P on NM_004072.3) | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100379681; called by muse, mutect2, varscan2
- CNGA1 | c.1327del p.T443Qfs*8 | Frame Shift Del (DEL) | VAF 63/286 reads (22%) | catalogued as rs772867912; called by mutect2, pindel, varscan2
- CNGA3 | c.1687C>T p.R563C | Missense Mutation (SNP) | VAF 91/297 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150153987, CM084800, COSV55628008; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNKSR3 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.009); catalogued as rs925966534, COSV70481099; called by muse, mutect2, varscan2
- CNKSR3 | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.392); catalogued as rs368781951; called by muse, mutect2, varscan2
- CNNM3 | c.1669T>C p.Y557H | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV59709128; called by muse, mutect2, varscan2
- CNOT11 | c.841C>T p.R281* | Nonsense Mutation (SNP) | VAF 39/107 reads (36%) | catalogued as COSV99179411; called by muse, mutect2, varscan2
- CNOT3 | c.41G>A p.C14Y | Missense Mutation (SNP) | VAF 127/415 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99652456; called by muse, mutect2, varscan2
- CNTN4 | c.2018G>A p.R673H | Missense Mutation (SNP) | VAF 80/426 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767479884, COSV61880394; called by muse, mutect2, varscan2
- CNTNAP2 | c.3262C>T p.R1088* | Nonsense Mutation (SNP) | VAF 46/82 reads (56%) | catalogued as rs766777011, COSV62164786; called by muse, mutect2, varscan2
- CNTNAP4 | c.1982C>T p.A661V | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs375479437; called by muse, mutect2, varscan2
- CNTNAP5 | c.3149C>A p.P1050H | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101444390; called by muse, mutect2, varscan2
- CNTRL | c.4969G>A p.G1657R | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.873); catalogued as rs771576806, COSV99444279; called by muse, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 28/54 reads (52%) | catalogued as rs374805044; called by mutect2, varscan2
- COG2 | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs370647410; called by muse, varscan2
- COL11A2 | c.2843dup p.P950Afs*19 (on ENST00000341947 / NM_080680.3; = p.P843Afs*19 on NM_080679.2) | Frame Shift Ins (INS) | VAF 31/280 reads (11%) | catalogued as COSV100554000; called by mutect2, pindel, varscan2
- COL14A1 | c.2642T>C p.I881T | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as COSV99921031; called by muse, mutect2, varscan2
- COL18A1 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as rs754701304, COSV100701016; called by muse, varscan2
- COL1A1 | c.2753G>A p.R918H | Missense Mutation (SNP) | VAF 61/176 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs181824088, COSV99868454; called by muse, mutect2, varscan2
- COL3A1 | c.4225A>G p.T1409A | Missense Mutation (SNP) | VAF 78/221 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV100483948; called by muse, mutect2, varscan2
- COL3A1 | c.4301G>A p.R1434H | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs138533702; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL7A1 | c.5744G>A p.R1915H | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs772888814, COSV60391197; called by muse, mutect2, varscan2
- COL7A1 | c.1814G>A p.R605Q | Missense Mutation (SNP) | VAF 54/95 reads (57%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs200890422; called by muse, mutect2, varscan2
- COL8A2 | c.2011G>A p.D671N | Missense Mutation (SNP) | VAF 51/94 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866697723, COSV100291456; called by muse, mutect2, varscan2
- COL9A1 | c.1610C>T p.T537M | Missense Mutation (SNP) | VAF 109/232 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs141895443, COSV57888254; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL9A3 | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.878); catalogued as rs373519549; called by muse, mutect2
- COMP | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.627); catalogued as rs144953891; called by muse, mutect2, varscan2
- COX4I1 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.978); catalogued as rs149461099; called by muse, mutect2, varscan2
- CPAMD8 | c.3563C>T p.P1188L (on ENST00000651564; = p.P1141L on NM_015692.5) | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775596217, COSV101488643; called by muse, mutect2, varscan2
- CPT2 | c.1152del p.F384Lfs*36 | Frame Shift Del (DEL) | VAF 19/50 reads (38%) | catalogued as rs1414678698; called by mutect2, pindel, varscan2
- CRAMP1 | c.2369G>A p.R790H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs773417565, COSV99245654; called by muse, mutect2, varscan2
- CRB1 | c.2207C>A p.T736N | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100958107; called by muse, mutect2, varscan2
- CREB1 | c.650C>T p.P217L (on ENST00000432329 / NM_134442.5; = p.P203L on NM_004379.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100783658; called by muse, mutect2, varscan2
- CRTAC1 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs200767311, COSV53996883; called by muse, mutect2, varscan2
- CSGALNACT1 | c.556T>G p.S186A | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100175846; called by muse, mutect2, varscan2
- CSMD1 | c.9949A>G p.T3317A (on ENST00000520002; = p.T3316A on NM_033225.6) | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.983); catalogued as COSV100155251; called by muse, mutect2, varscan2
- CSMD1 | c.9320G>C p.G3107A (on ENST00000520002; = p.G3106A on NM_033225.6) | Missense Mutation (SNP) | VAF 206/462 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1429592019, COSV100155255; called by muse, mutect2, varscan2
- CSNK1G2 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 41/61 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99730338; called by muse, mutect2, varscan2
- CSNK1G3 | c.888del p.F296Lfs*9 | Frame Shift Del (DEL) | VAF 5/36 reads (14%) | catalogued as rs1192761448; called by mutect2, pindel
- CSPG4 | c.3255C>A p.D1085E | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100414305; called by muse, mutect2, varscan2
- CSPG5 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV99274325; called by muse, mutect2, varscan2
- CUBN | c.9028G>A p.A3010T | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as rs756775921, COSV64710332; called by muse, mutect2, varscan2
- CWC22 | c.196A>C p.M66L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV55427994, COSV99844750; called by muse, mutect2
- CXXC1 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.876); catalogued as rs200536058, COSV99497483; called by muse, mutect2, varscan2
- CYC1 | c.276dup p.S93Qfs*26 | Frame Shift Ins (INS) | VAF 27/120 reads (23%) | catalogued as rs756254049; called by mutect2, varscan2
- CYP21A2 | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.459); catalogued as rs376421504; called by muse, mutect2, varscan2
- CYP46A1 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 393/516 reads (76%) | SIFT tolerated (0.29); PolyPhen benign (0.069); catalogued as rs1359685294, COSV99952949; called by muse, mutect2, varscan2
- CYP4F11 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 96/266 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as rs144938795; called by muse, mutect2, varscan2
- CYTH3 | c.960G>C p.E320D (on ENST00000396741; = p.E319D on NM_004227.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/160 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV100085037; called by muse, mutect2, varscan2
- CZIB | c.445G>T p.G149* | Nonsense Mutation (SNP) | VAF 23/56 reads (41%) | catalogued as COSV99598411; called by muse, mutect2, varscan2
- DAAM1 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759856885, CM154571, COSV100658513; called by muse, mutect2, varscan2
- DAGLB | c.1703G>A p.R568H | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369940779; called by muse, varscan2
- DAND5 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 51/77 reads (66%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as rs373817477; called by muse, mutect2, varscan2
- DAO | c.194+1G>A p.X65_splice | Splice Site (SNP) | VAF 72/191 reads (38%) | catalogued as rs762930737, CS155533, COSV57323690; called by muse, mutect2, varscan2
- DBNL | c.770C>T p.P257L (on ENST00000448521 / NM_001014436.3; = p.P258L on NM_014063.7) | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs112769270, COSV51977109; called by muse, mutect2, varscan2
- DCAF1 | c.1336C>A p.L446M | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs868965477; called by muse, mutect2, varscan2
- DCC | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.278); catalogued as rs768831554, COSV59091314; called by muse, mutect2, varscan2
- DCLK1 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55192408; called by muse, mutect2, varscan2
- DCUN1D2 | c.649C>A p.L217M | Missense Mutation (SNP) | VAF 92/249 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100215389; called by muse, mutect2, varscan2
- DDI1 | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV56378852; called by muse, mutect2, varscan2
- DDIT3 | c.298G>T p.G100W | Missense Mutation (SNP) | VAF 44/232 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV100007790; called by muse, mutect2, varscan2
- DDX11 | c.1210G>A p.G404S | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0.018); catalogued as COSV52501020, COSV99300511; called by muse, mutect2
- DDX54 | c.1719G>A p.A573= | Splice Region (SNP) | VAF 11/31 reads (35%) | catalogued as rs756569371, COSV58372361, COSV58376412; called by muse, mutect2, varscan2
- DDX54 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs891338950; called by muse, mutect2
- DEF8 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV99240848, COSV99240850; called by muse, mutect2, varscan2
- DEGS1 | c.155T>A p.L52H | Missense Mutation (SNP) | VAF 34/334 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV100083492; called by muse, mutect2
- DEGS2 | c.569C>T p.T190M | Missense Mutation (SNP) | VAF 85/104 reads (82%) | SIFT tolerated (0.23); PolyPhen benign (0.206); catalogued as rs199587189; called by muse, mutect2, varscan2
- DENND11 | c.469C>A p.L157I | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.286); catalogued as COSV101530693, COSV101530737; called by mutect2, varscan2
- DENND1A | c.2402G>A p.R801H | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs768909607, COSV101012396; called by muse, varscan2
- DENND1A | c.1773G>T p.K591N | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV101012397; called by muse, mutect2, varscan2
- DENND2D | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (1); PolyPhen possibly damaging (0.721); catalogued as rs769717736, COSV100718856; called by muse, mutect2, varscan2
- DENND4B | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.733); catalogued as rs749288468, COSV63407564; called by muse, mutect2, varscan2
- DENND4C | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 57/345 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100991590; called by muse, mutect2, varscan2
- DHRS13 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs775606900, COSV101129087; called by muse, varscan2
- DHRS9 | c.669del p.K223Nfs*25 | Frame Shift Del (DEL) | VAF 17/72 reads (24%) | catalogued as rs756920263; called by mutect2, varscan2
- DHX30 | c.2494G>A p.A832T (on ENST00000445061 / NM_138615.3; = p.A793T on NM_014966.3) | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV99276553; called by muse, mutect2, varscan2
- DHX37 | c.2497C>T p.R833W | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs780796755, COSV100439608; called by muse, mutect2, varscan2
- DIAPH3 | c.2111C>T p.S704L (on ENST00000400324 / NM_001042517.2; = p.S441L on NM_030932.3) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs762124184, COSV57364816, COSV57365214; called by muse, mutect2, varscan2
- DIP2C | c.4615C>T p.R1539* | Nonsense Mutation (SNP) | VAF 41/103 reads (40%) | catalogued as COSV99794201; called by muse, mutect2, varscan2
- DISP1 | c.3444del p.K1148Nfs*26 | Frame Shift Del (DEL) | VAF 28/248 reads (11%) | catalogued as rs1478802964; called by mutect2, pindel, varscan2
- DLAT | c.723del p.V242Wfs*5 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs782029228, COSV54771743; called by mutect2, varscan2
- DLC1 | c.911A>C p.N304T | Missense Mutation (SNP) | VAF 76/241 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.478); catalogued as COSV52327963, COSV99364612; called by muse, mutect2, varscan2
- DLG5 | c.3848C>T p.P1283L | Missense Mutation (SNP) | VAF 60/181 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1282713034, COSV64947568; called by muse, mutect2, varscan2
- DLGAP1 | c.2455C>T p.R819W | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs1339514297, COSV59831176; called by muse, mutect2, varscan2
- DMBX1 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as rs760474949, COSV63601963; called by muse, mutect2, varscan2
- DMXL2 | c.5393G>A p.R1798H | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99196094; called by muse, mutect2, varscan2
- DNAH11 | c.3446T>G p.F1149C | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100181483; called by muse, mutect2, varscan2
- DNAH11 | c.12992C>T p.T4331M | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs760795047, COSV100181484; called by muse, mutect2, varscan2
- DNAH17 | c.12390dup p.N4131Qfs*13 | Frame Shift Ins (INS) | VAF 70/221 reads (32%) | catalogued as rs757601640; called by mutect2, varscan2
- DNAH17 | c.7084G>A p.A2362T | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.255); catalogued as rs377570773; called by muse, mutect2, varscan2
- DNAH17 | c.2314C>T p.R772* | Nonsense Mutation (SNP) | VAF 50/133 reads (38%) | catalogued as rs201020434, COSV101103907; called by muse, mutect2, varscan2
- DNAH2 | c.2098C>T p.R700C | Missense Mutation (SNP) | VAF 55/302 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs188435233, COSV66719213; called by muse, mutect2, varscan2
- DNAH2 | c.4291C>T p.R1431C | Missense Mutation (SNP) | VAF 98/250 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as rs777742686, COSV101209662; called by muse, mutect2, varscan2
- DNAH2 | c.5749G>A p.E1917K | Missense Mutation (SNP) | VAF 187/507 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as rs771959734, COSV101209101; called by muse, mutect2, varscan2
- DNAH5 | c.877del p.R293Dfs*12 | Frame Shift Del (DEL) | VAF 66/364 reads (18%) | catalogued as COSV54201852; called by mutect2, pindel, varscan2
- DNAH7 | c.12040C>G p.R4014G | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100413580, COSV100418237; called by muse, mutect2, varscan2
- DNAH7 | c.3221dup p.L1074Ffs*4 | Frame Shift Ins (INS) | VAF 26/80 reads (33%) | catalogued as rs763352877; called by mutect2, varscan2
- DNAH8 | c.6091C>T p.L2031F | Missense Mutation (SNP) | VAF 32/264 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59458429; called by muse, mutect2, varscan2
- DNAH9 | c.11071G>A p.D3691N | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as rs138333222; called by muse, mutect2, varscan2
- DNAI3 | c.2005A>C p.T669P | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV99642557; called by muse, mutect2, varscan2
- DNHD1 | c.13219C>T p.R4407* | Nonsense Mutation (SNP) | VAF 8/16 reads (50%) | catalogued as rs1030679647, COSV54441033; called by muse, mutect2, varscan2
- DNM1L | c.1916G>A p.R639Q (on ENST00000549701 / NM_012062.5; = p.R602Q on NM_005690.4) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99845807, COSV99846146; called by muse, mutect2, varscan2
- DNM2 | c.1346A>G p.Y449C | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100118276; called by muse, mutect2, varscan2
- DOCK3 | c.1342A>G p.M448V | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs555218926, COSV99816034; called by muse, mutect2, varscan2
- DOCK3 | c.2326C>T p.R776* | Nonsense Mutation (SNP) | VAF 16/30 reads (53%) | catalogued as rs772603580, COSV99816037; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 41/80 reads (51%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK4 | c.4258C>T p.R1420* | Nonsense Mutation (SNP) | VAF 20/44 reads (45%) | catalogued as rs1186684235, COSV101447821; called by muse, mutect2, varscan2
- DOCK5 | c.1628C>T p.S543L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs781464699, COSV52409924; called by muse, mutect2, varscan2
- DOP1A | c.4351A>G p.M1451V | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as rs754466934, COSV99383188; called by muse, varscan2
- DOP1B | c.146A>G p.Q49R | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751600011, COSV99536086; called by muse, mutect2, varscan2
- DPYD | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 71/165 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs778601245, COSV64602983; called by muse, mutect2, varscan2
- DSCAM | c.4054G>A p.E1352K | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV101261803; called by muse, mutect2, varscan2
- DST | c.22004C>T p.T7335M (on ENST00000361203 / NM_001374722.1; = p.T5045M on NM_015548.5) | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs532258725, COSV99758258; called by muse, mutect2, varscan2
- DST | c.15941C>T p.T5314M (on ENST00000361203 / NM_001374722.1; = p.T2902M on NM_015548.5) | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.967); catalogued as rs756527130, COSV55014242, COSV55029896; called by muse, mutect2, varscan2
- DSTYK | c.1652G>A p.R551H | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.891); catalogued as rs765772515, COSV65687055; called by muse, mutect2, varscan2
- DTL | c.2074G>A p.G692R | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs369056190, COSV65342911; called by muse, mutect2, varscan2
- DTX1 | c.1007T>C p.M336T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV99986653; called by muse, mutect2, varscan2
- DTX4 | c.1711G>A p.V571I | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs376862310; called by muse, mutect2
- DUOX1 | c.3153C>A p.F1051L | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV100368623; called by muse, mutect2, varscan2
- DUOX2 | c.4445C>T p.T1482M | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750546082, COSV66534894; called by muse, mutect2, varscan2
- DUSP12 | c.721A>C p.S241R | Missense Mutation (SNP) | VAF 32/386 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.528); catalogued as COSV100909789; called by muse, mutect2
- DYNC1H1 | c.6847G>A p.V2283M | Missense Mutation (SNP) | VAF 33/194 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as rs374569905; called by muse, mutect2, varscan2
- DYNC1H1 | c.13738G>A p.A4580T | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV100795608, COSV64143956; called by muse, mutect2, varscan2
- DYNC1I2 | c.1220T>A p.I407N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV99784446; called by muse, mutect2
- DYNC2I1 | c.1580del p.N527Ifs*23 | Frame Shift Del (DEL) | VAF 51/103 reads (50%) | catalogued as rs751377941; called by mutect2, varscan2
- DYSF | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 91/243 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as rs764849844, COSV50308878; called by muse, mutect2, varscan2
- DZIP1 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1406067552, COSV61266237; called by muse, mutect2, varscan2
- ECT2 | c.2024G>A p.R675Q (on ENST00000392692 / NM_001349098.2; = p.R644Q on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.372); catalogued as rs146823982; called by muse, mutect2, varscan2
- EDA | c.504C>T p.G168= | Splice Region (SNP) | VAF 10/24 reads (42%) | catalogued as COSV65782887; called by muse, mutect2, varscan2
- EDAR | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 70/178 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.08); catalogued as COSV99304478; called by muse, mutect2, varscan2
- EDNRB | c.1147del p.Y383Ifs*3 (on ENST00000377211 / NM_001201397.1; = p.Y293Ifs*3 on NM_000115.5) | Frame Shift Del (DEL) | VAF 18/96 reads (19%) | catalogued as rs769735757; ClinVar: risk factor; called by mutect2, pindel, varscan2
- EDRF1 | c.3481T>C p.S1161P (on ENST00000356792 / NM_001202438.2; = p.S1127P on NM_015608.2) | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100524166; called by muse, mutect2, varscan2
- EEF1A2 | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.021); catalogued as rs770611931, COSV53208418; called by muse, mutect2, varscan2
- EEF1D | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs751616584, COSV100415151; called by muse, mutect2, varscan2
- EEF2 | c.1597A>G p.M533V | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as COSV100501072; called by muse, mutect2, varscan2
- EEPD1 | c.1678C>T p.R560* | Nonsense Mutation (SNP) | VAF 16/52 reads (31%) | catalogued as rs1223871838, COSV54201087; called by muse, mutect2, varscan2
- EGFLAM | c.2351C>T p.A784V | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as rs200259259, COSV100380738, COSV59297476; called by muse, mutect2, varscan2
- EIF3E | c.661_664del p.V221Sfs*36 | Frame Shift Del (DEL) | VAF 46/200 reads (23%) | catalogued as rs762916048; called by pindel, varscan2
- EIF4E1B | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs765322594, COSV53782101; called by muse, mutect2, varscan2
- EIF4G3 | c.3006G>T p.E1002D | Missense Mutation (SNP) | VAF 93/207 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV99946032; called by muse, mutect2, varscan2
- ELMO1 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.995); catalogued as rs751048183, COSV100166577; called by muse, mutect2, varscan2
- ELMOD1 | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 23/49 reads (47%) | catalogued as COSV99760554; called by muse, mutect2, varscan2
- ELMOD3 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs779560360, COSV100226554; called by muse, mutect2, varscan2
- ENO1 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99319055; called by mutect2, varscan2
- ENTPD4 | c.1760G>A p.R587H | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.221); catalogued as rs202242195, COSV100652795; called by muse, mutect2
- ENY2 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs750806375, COSV53455799; called by muse, mutect2, varscan2
- EP300 | c.3226C>T p.R1076C | Missense Mutation (SNP) | VAF 251/395 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750235600, COSV54335639, COSV54337065; called by muse, varscan2
- EPB41L3 | c.2489C>T p.T830M | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs771374021, COSV100550659; called by muse, mutect2, varscan2
- EPC2 | c.2357A>G p.N786S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.982); catalogued as COSV99310369; called by muse, mutect2, varscan2
- EPHA1 | c.2597A>G p.D866G | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.426); catalogued as COSV99314972; called by muse, mutect2, varscan2
- EPHB4 | c.2152G>A p.V718M | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs777774115, COSV100639536; called by muse, varscan2
- EPHB4 | c.1742A>G p.Y581C | Missense Mutation (SNP) | VAF 116/638 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1370137843, COSV100639702; called by muse, mutect2, varscan2
- EPN1 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as rs1368527234, COSV99322533; called by muse, mutect2
- EPN2 | c.1703G>A p.R568Q | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as rs747842632, COSV100127802; called by muse, mutect2, varscan2
- ERCC2 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1054768577; called by muse, mutect2
- ERCC6L2 | c.1649A>G p.D550G | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV99999108; called by muse, mutect2, varscan2
- ERI3 | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 66/297 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.086); catalogued as COSV64830498; called by muse, mutect2, varscan2
- ERICH3 | c.2827G>A p.G943R | Missense Mutation (SNP) | VAF 90/188 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs764159125, COSV58602064; called by muse, mutect2, varscan2
- ERN2 | c.2320del p.Q774Rfs*35 | Frame Shift Del (DEL) | VAF 151/484 reads (31%) | catalogued as rs1567242682; called by mutect2, pindel, varscan2
- ERO1B | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 133/195 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99934460; called by muse, mutect2, varscan2
- ESAM | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54034661; called by muse, mutect2, varscan2
- ESPN | c.1355del p.P452Hfs*11 | Frame Shift Del (DEL) | VAF 12/19 reads (63%) | catalogued as rs1409006016, COSV64704219; called by mutect2, pindel, varscan2
- ESYT2 | c.1216G>T p.G406* (on ENST00000613624; = p.G330* on NM_020728.3) | Nonsense Mutation (SNP) | VAF 23/158 reads (15%) | catalogued as COSV99277432; called by muse, mutect2, varscan2
- ETFDH | c.1271A>G p.Q424R | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as COSV100310186; called by muse, mutect2, varscan2
- EXOC3L1 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.454); catalogued as rs762545783, COSV99334043; called by muse, mutect2, varscan2
- EXTL3 | c.2137G>A p.V713I | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); catalogued as rs774554716, COSV99594463; called by muse, mutect2, varscan2
- F11 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV53005254, COSV99251981; called by muse, mutect2, varscan2
- F8 | c.3784G>A p.A1262T | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100812151; called by muse, mutect2, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 18/66 reads (27%) | catalogued as rs766589051; called by mutect2, pindel, varscan2
- FAM117B | c.1250C>T p.S417L | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.941); catalogued as rs781634515, COSV57420623; called by muse, mutect2, varscan2
- FAM189B | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1217356266, COSV100227015; called by muse, mutect2, varscan2
- FAM193B | c.1385G>A p.R462Q | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1009673512, COSV61557366; called by muse, mutect2, varscan2
- FAM210A | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV100452564; called by muse, mutect2, varscan2
- FAM234A | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs201149518; called by muse, mutect2, varscan2
- FAM3B | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs970237251, COSV63613053; called by muse, mutect2, varscan2
- FAM47B | c.403C>A p.P135T | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as COSV100264749; called by muse, mutect2, varscan2
- FAM53A | c.974G>A p.C325Y | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV100357345; called by muse, mutect2, varscan2
- FAM83C | c.1445G>A p.R482Q | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs781027964, COSV100981763; called by muse, mutect2, varscan2
- FAM83D | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 72/197 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as rs370045194, COSV99028122; called by muse, mutect2, varscan2
- FAM90A1 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 72/145 reads (50%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs766658993, COSV56713642; called by muse, mutect2, varscan2
- FAM9A | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 109/243 reads (45%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs1396516531, COSV66813011; called by muse, varscan2
- FANCA | c.4105G>A p.V1369M | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.366); catalogued as rs201225325, COSV99235475; called by muse, mutect2, varscan2
- FANCI | c.1804C>T p.R602* | Nonsense Mutation (SNP) | VAF 84/196 reads (43%) | catalogued as rs1432325198, COSV55528103; called by muse, mutect2
- FASN | c.3487G>A p.G1163R | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.246); catalogued as rs201281021; called by muse, mutect2, varscan2
- FAT1 | c.9988G>A p.D3330N | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71676226; called by muse, mutect2, varscan2
- FAT1 | c.7667G>A p.R2556Q | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768745435, COSV101499264; called by muse, mutect2, varscan2
- FAT1 | c.3235G>A p.V1079I | Missense Mutation (SNP) | VAF 86/222 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs143694311; called by muse, varscan2
- FAT3 | c.8308C>T p.R2770C | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.864); catalogued as rs558485124, COSV99972525; called by muse, mutect2, varscan2
- FAT4 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs370926669; called by muse, mutect2, varscan2
- FAXDC2 | c.881A>T p.D294V | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100304233; called by muse, mutect2, varscan2
- FBN2 | c.5038G>T p.G1680C | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99331586; called by muse, mutect2, varscan2
- FBXL7 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.67); catalogued as rs775944574, COSV61640916, COSV61651772; called by muse, varscan2
- FBXL7 | c.1373C>T p.T458M | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs776522515, COSV61642885; called by muse, varscan2
- FBXO21 | c.1750C>T p.R584C (on ENST00000330622 / NM_033624.3; = p.R577C on NM_015002.3) | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs372082361; called by muse, mutect2, varscan2
- FBXO40 | c.1361del p.G454Dfs*11 | Frame Shift Del (DEL) | VAF 33/97 reads (34%) | catalogued as COSV100573072, COSV57524870; called by mutect2, pindel, varscan2
- FCGBP | c.447dup p.G150Rfs*68 | Frame Shift Ins (INS) | VAF 21/82 reads (26%) | catalogued as rs765680504; called by mutect2, pindel, varscan2
- FCHO1 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs141405200; called by muse, mutect2, varscan2
- FCRL5 | c.2879C>T p.A960V | Missense Mutation (SNP) | VAF 135/747 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as rs201400157, COSV62513719; called by muse, mutect2, varscan2
- FEM1A | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54164957; called by muse, mutect2, varscan2
- FER1L6 | c.2799del p.R934Gfs*56 | Frame Shift Del (DEL) | VAF 17/127 reads (13%) | catalogued as rs770147778; called by mutect2, pindel, varscan2
- FER1L6 | c.4798G>A p.V1600M | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs201570190, COSV67549003; called by muse, mutect2, varscan2
- FES | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 9/72 reads (13%) | catalogued as COSV51575494; called by muse, mutect2, varscan2
- FGF18 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs371575721, COSV99209349; called by muse, mutect2, varscan2
- FGF9 | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV101211054; called by muse, mutect2, varscan2
- FGFR1 | c.1982G>A p.R661Q (on ENST00000447712 / NM_023110.3; = p.R659Q on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1257312391, CM162424, COSV58327742; called by muse, mutect2, varscan2
- FGFR4 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs754633250, COSV99451165; called by muse, mutect2, varscan2
- FGFRL1 | c.956A>G p.Y319C | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99294943; called by muse, mutect2, varscan2
- FGR | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as COSV100925930; called by muse, mutect2, varscan2
- FHL1 | c.71G>A p.G24D | Missense Mutation (SNP) | VAF 94/319 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV100600810; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 37/79 reads (47%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FIGN | c.1264T>C p.Y422H | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.462); catalogued as COSV100293109; called by muse, mutect2, varscan2
- FKBP6 | c.325A>G p.R109G | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99334375; called by muse, mutect2, varscan2
- FLNC | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100368615, COSV100369000; called by muse, mutect2, varscan2
- FLNC | c.3511G>A p.G1171S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as rs769490872, COSV57953088; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLOT2 | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs749079749, COSV101204819; called by muse, mutect2, varscan2
- FLYWCH1 | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs112444415; called by muse, mutect2, varscan2
- FMNL1 | c.734G>A p.S245N | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as COSV100057103; called by muse, mutect2, varscan2
- FN1 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100118565; called by muse, mutect2
- FNDC1 | c.2038G>A p.V680I | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV99795788; called by muse, mutect2, varscan2
- FNDC1 | c.4849T>C p.Y1617H | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99797398; called by muse, mutect2, varscan2
- FRAS1 | c.1887del p.K630Rfs*67 | Frame Shift Del (DEL) | VAF 14/101 reads (14%) | catalogued as rs776570778; called by mutect2, varscan2
- FREM2 | c.6736G>T p.A2246S | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as COSV99751580; called by muse, mutect2, varscan2
- FRMD7 | c.910C>T p.R304* | Nonsense Mutation (SNP) | VAF 54/98 reads (55%) | catalogued as rs1043225481, CM081618, COSV53745157; called by muse, mutect2, varscan2
- FRY | c.3068G>A p.R1023Q | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs1316106726, COSV100970051; called by muse, mutect2, varscan2
- FRY | c.5647G>A p.A1883T | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT tolerated (0.38); PolyPhen benign (0.07); catalogued as COSV100970052; called by muse, mutect2, varscan2
- FSHR | c.416A>G p.H139R | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100438373; called by muse, mutect2, varscan2
- GABBR2 | c.2396G>A p.R799Q | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.921); catalogued as rs1157758873, COSV99412056; called by muse, mutect2, varscan2
- GABRA2 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62914797; called by muse, mutect2, varscan2
- GABRA3 | c.1441C>T p.R481W | Missense Mutation (SNP) | VAF 75/121 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV64800818; called by muse, mutect2, varscan2
- GABRA5 | c.1311C>A p.F437L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100165962, COSV59478642; called by muse, mutect2, varscan2
- GABRR2 | c.952G>A p.V318I | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.949); catalogued as rs760231917, COSV101299062; called by muse, mutect2, varscan2
- GAP43 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.251); catalogued as rs11557765, COSV100526061; called by muse, mutect2, varscan2
- GARNL3 | c.2957C>T p.A986V | Missense Mutation (SNP) | VAF 76/168 reads (45%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV100150808; called by muse, mutect2, varscan2
- GATB | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766387123, COSV99859350; called by muse, mutect2, varscan2
- GBA2 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs760492879, COSV62305411; called by muse, mutect2, varscan2
- GCK | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as rs764575801, COSV99790000; called by muse, varscan2
- GFRA2 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.75); catalogued as rs1277283983, COSV100152186; called by muse, mutect2, varscan2
- GGA2 | c.340T>G p.L114V | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.999); catalogued as rs1379376238, COSV100564903; called by muse, mutect2, varscan2
- GIPC1 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as rs201549025, COSV61774935; called by muse, varscan2
- GIT1 | c.1562del p.G521Afs*19 | Frame Shift Del (DEL) | VAF 76/229 reads (33%) | catalogued as COSV56402468, COSV56402721; called by mutect2, varscan2
- GLE1 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.148); catalogued as rs148746665; called by muse, mutect2, varscan2
- GLI3 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 68/167 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs1025335707, COSV67886291; called by muse, mutect2, varscan2
- GLYATL2 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0.028); catalogued as rs201965758, COSV99780602; called by muse, mutect2, varscan2
- GMPR | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 41/308 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as rs747618542, COSV52475095; called by muse, mutect2, varscan2
- GNAS | c.1802G>A p.R601Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as rs1376619714, COSV100008076; called by muse, mutect2, varscan2
- GNL3L | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.103); catalogued as rs866852111, COSV60577331; called by muse, mutect2, varscan2
- GNMT | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs946974235, COSV55103952; called by muse, mutect2, varscan2
- GNPTAB | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.186); catalogued as COSV100172528; called by muse, mutect2, varscan2
- GOLGA2 | c.1679C>T p.S560L | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.102); catalogued as rs768763105, COSV100360481; called by muse, mutect2, varscan2
- GOLIM4 | c.1891del p.R631Gfs*87 | Frame Shift Del (DEL) | VAF 45/220 reads (20%) | catalogued as rs1210775698; called by mutect2, pindel, varscan2
- GOSR2 | c.113G>A p.S38N (on ENST00000393456 / NM_001321134.1; = p.S56N on NM_004287.5) | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99846345; called by muse, mutect2, varscan2
- GPER1 | c.370T>C p.Y124H | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV52468435, COSV52470568; called by muse, mutect2, varscan2
- GPLD1 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 29/229 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as rs766726890, COSV100015660; called by muse, mutect2, varscan2
- GPR119 | c.880G>T p.A294S | Missense Mutation (SNP) | VAF 58/90 reads (64%) | SIFT tolerated (0.18); PolyPhen benign (0.154); catalogued as COSV99358745; called by muse, varscan2
- GPR135 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV67749879; called by muse, mutect2, varscan2
- GPR137 | c.1198C>T p.L400F | Missense Mutation (SNP) | VAF 96/242 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV100464628; called by muse, mutect2, varscan2
- GPR45 | c.853G>A p.V285I | Missense Mutation (SNP) | VAF 139/386 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as COSV51522825; called by muse, mutect2, varscan2
- GPR50 | c.610G>A p.V204M | Missense Mutation (SNP) | VAF 131/203 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as rs1288793743, COSV54436783; called by muse, mutect2, varscan2
- GPR68 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as rs1416491283, COSV99473624; called by muse, mutect2, varscan2
- GPR83 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.465); catalogued as rs149566608; called by muse, mutect2, varscan2
- GPR84 | c.553A>G p.I185V | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs1444701522, COSV99910179; called by muse, mutect2, varscan2
- GPRC5C | c.766A>G p.M256V (on ENST00000652232; = p.M211V on NM_018653.4) | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV100703053; called by muse, mutect2, varscan2
- GPX3 | c.445T>C p.Y149H | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100161900; called by muse, mutect2, varscan2
- GRIA2 | c.2480C>T p.A827V | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52386099, COSV99646299; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 47/128 reads (37%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIK5 | c.1961C>T p.S654L | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99491560; called by muse, mutect2, varscan2
- GRIN2B | c.4268C>T p.A1423V | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV101663241; called by muse, mutect2, varscan2
- GRK7 | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.13); catalogued as rs773113276, COSV99379910; called by muse, mutect2, varscan2
- GRK7 | c.890C>T p.S297L | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as rs201386342, COSV53821577; called by muse, mutect2, varscan2
- GRM2 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV56583171, COSV56584089; called by muse, mutect2, varscan2
- GRM6 | c.727del p.V243Sfs*21 | Frame Shift Del (DEL) | VAF 54/274 reads (20%) | catalogued as rs281865186, CM1514172; ClinVar: not provided; called by mutect2, pindel, varscan2
- GSE1 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.307); catalogued as rs199912131, COSV99497401; called by muse, mutect2, varscan2
- GSTP1 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as rs1025117296, COSV101282048; called by muse, mutect2, varscan2
- GTF2F2 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs1490026973, COSV100477589; called by muse, mutect2, varscan2
- GUCY1B1 | c.353C>A p.P118H | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100026029; called by muse, mutect2, varscan2
- GUCY2D | c.2729C>T p.T910I | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV54698172; called by muse, mutect2, varscan2
- H1-7 | c.352G>A p.G118S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs756417274; called by mutect2, varscan2
- H2AC20 | c.305C>T p.T102I | Missense Mutation (SNP) | VAF 24/229 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.108); catalogued as COSV100480238, COSV58612189; called by muse, mutect2, varscan2
- HAND1 | c.406_407del p.L136Afs*29 | Frame Shift Del (DEL) | VAF 38/116 reads (33%) | catalogued as rs765936211; called by pindel, varscan2
- HAUS3 | c.1195C>T p.R399W | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs148548454, COSV54723596; called by muse, mutect2, varscan2
- HCFC1 | c.1099C>A p.P367T | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100129718; called by muse, mutect2, varscan2
- HCN3 | c.1537C>T p.R513C | Missense Mutation (SNP) | VAF 88/128 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as rs946623627, COSV61360570; called by muse, mutect2, varscan2
- HCN3 | c.1672C>T p.R558C | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.731); catalogued as rs563414640, COSV100713090; called by muse, mutect2, varscan2
- HDAC5 | c.297G>T p.Q99H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99871185; called by muse, mutect2, varscan2
- HDLBP | c.3250G>A p.V1084M | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100192151; called by muse, mutect2, varscan2
- HECA | c.1004dup p.H336Tfs*25 | Frame Shift Ins (INS) | VAF 22/108 reads (20%) | catalogued as rs771658394; called by mutect2, varscan2
- HECA | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1468282093, COSV100866283; called by muse, mutect2, varscan2
- HECTD4 | c.13100del p.P4367Qfs*21 | Frame Shift Del (DEL) | VAF 34/184 reads (18%) | catalogued as rs746492036; called by mutect2, varscan2
- HERC1 | c.9509G>A p.R3170H | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs369547448; called by muse, mutect2, varscan2
- HERC1 | c.5791G>A p.E1931K | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV101497102; called by muse, mutect2, varscan2
- HERC2 | c.5033T>C p.L1678P | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99877668; called by muse, mutect2, varscan2
- HERC2 | c.541del p.S181Vfs*85 | Frame Shift Del (DEL) | VAF 24/109 reads (22%) | catalogued as rs1449081007; called by mutect2, pindel, varscan2
- HES3 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100928637; called by muse, mutect2, varscan2
- HFM1 | c.4072G>T p.G1358* | Nonsense Mutation (SNP) | VAF 53/141 reads (38%) | catalogued as COSV99646648; called by muse, mutect2, varscan2
- HGS | c.1054G>A p.V352M | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as rs1207628877, COSV61268597, COSV61269649; called by muse, mutect2, varscan2
- HHIP | c.758T>C p.I253T | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT tolerated (0.31); PolyPhen probably damaging (1); catalogued as rs780145807, COSV56844446, COSV99668110; called by muse, mutect2, varscan2
- HIGD1A | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.26); catalogued as rs1316067298, COSV100359191; called by muse, mutect2, varscan2
- HIVEP2 | c.1816G>A p.V606M | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV50072993, COSV99177178; called by muse, mutect2, varscan2
- HIVEP3 | c.2443C>T p.P815S | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.039); catalogued as COSV99914356; called by muse, varscan2
- HK2 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 183/612 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.031); catalogued as rs1163770214, COSV51877011; called by muse, varscan2
- HK3 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs754415631, COSV99459679; called by muse, varscan2
- HLA-B | c.500C>T p.T167I | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as rs151341275, COSV101318302; called by muse, mutect2
- HMCN1 | c.6812C>T p.A2271V | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as rs747638841, COSV54890259; called by muse, mutect2
- HOMEZ | c.1127del p.L376Yfs*14 | Frame Shift Del (DEL) | VAF 13/90 reads (14%) | catalogued as rs755016625; called by mutect2, varscan2
- HORMAD1 | c.557del p.P186Qfs*25 | Frame Shift Del (DEL) | VAF 48/170 reads (28%) | catalogued as COSV59273289; called by mutect2, pindel, varscan2
- HOXA3 | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 56/190 reads (29%) | catalogued as COSV100415767; called by muse, mutect2, varscan2
- HR | c.3431A>C p.E1144A | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100456092; called by muse, mutect2, varscan2
- HSP90B1 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs368374645; called by muse, mutect2, varscan2
- HSPA4L | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs768194196, COSV56545185; called by muse, mutect2, varscan2
- HSPBP1 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.554); catalogued as rs776670838, COSV99729357; called by muse, mutect2
- HTT | c.2634G>A p.R878= | Splice Region (SNP) | VAF 68/139 reads (49%) | catalogued as COSV100751408; called by muse, mutect2, varscan2
- HTT | c.2906C>T p.T969M | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.542); catalogued as rs759239953, COSV100751410; called by muse, mutect2, varscan2
- HYAL1 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs782692817, COSV56497715; called by muse, mutect2, varscan2
- HYOU1 | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.912); catalogued as rs782034654, COSV68215840; called by muse, mutect2, varscan2
- ICAM1 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs1568295295, COSV53424349, COSV53427385; called by muse, mutect2, varscan2
- ICAM3 | c.668del p.P223Rfs*21 | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | catalogued as rs759151580; called by mutect2, pindel, varscan2
- ICE1 | c.6476C>T p.A2159V | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs375797140; called by muse, mutect2, varscan2
- IGDCC4 | c.2536+2T>C p.X846_splice | Splice Site (SNP) | VAF 13/55 reads (24%) | catalogued as COSV61538329; called by muse, mutect2, varscan2
- IGF1R | c.976G>A p.G326S | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99163626; called by muse, varscan2
- IGFALS | c.1337T>G p.L446R | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99236776; called by muse, mutect2, varscan2
- IGFN1 | c.2417C>T p.A806V (on ENST00000295591 / NM_001367841.1; = p.A3263V on NM_001164586.2) | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as rs748235310, COSV99813789; called by muse, mutect2, varscan2
- IGSF9 | c.154del p.L52Cfs*79 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | catalogued as rs753928344; called by mutect2, varscan2
- IGSF9B | c.3451G>A p.E1151K | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as rs768462205, COSV100318670; called by muse, mutect2, varscan2
- IL13 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376870298, COSV100449426; called by muse, mutect2, varscan2
- IL17RE | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.11); catalogued as rs1298869570, COSV99925368; called by muse, mutect2
- IL31RA | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.033); catalogued as COSV99763699; called by muse, mutect2, varscan2
- IL4I1 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs776375305, COSV62010206; called by muse, varscan2
- ILDR2 | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs975956156, COSV54835092; called by muse, mutect2
- ILVBL | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as rs752735199, COSV99655206; called by muse, varscan2
- INCA1 | c.335G>A p.R112Q (on ENST00000574617 / NM_001167986.1; = p.R97Q on NM_213726.2) | Missense Mutation (SNP) | VAF 131/503 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.272); catalogued as rs750197169, COSV61788845; called by muse, mutect2, varscan2
- INKA2 | c.536G>T p.G179V | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.111); catalogued as rs1441239950, COSV100615920, COSV61878290; called by muse, varscan2
- INPP4B | c.2452del p.R818Efs*4 | Frame Shift Del (DEL) | VAF 11/62 reads (18%) | catalogued as COSV53751800; called by mutect2, pindel, varscan2
- IQCD | c.1058C>T p.A353V (on ENST00000416617 / NM_001330452.2; = p.A251V on NM_138451.3) | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV55323253; called by muse, mutect2, varscan2
- IQGAP2 | c.3986C>T p.A1329V | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs148122303, COSV57177568; called by muse, mutect2, varscan2
- IQGAP3 | c.721C>T p.R241* | Nonsense Mutation (SNP) | VAF 39/258 reads (15%) | catalogued as rs755115439, COSV100752473; called by muse, mutect2, varscan2
- IREB2 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 87/225 reads (39%) | catalogued as COSV51924283; called by muse, mutect2, varscan2
- ITGA2 | c.1811T>C p.I604T | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs199827065, COSV99671874; called by muse, mutect2, varscan2
- ITGA5 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.503); catalogued as rs375602887; called by muse, mutect2, varscan2
- ITLN2 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.451); catalogued as rs530710369, COSV100600775; called by muse, mutect2, varscan2
- ITPR1 | c.1127G>A p.R376H (on ENST00000354582; = p.R361H on NM_002222.7) | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.636); catalogued as rs1260045423, CM161444, COSV57001875; called by muse, mutect2, varscan2
- ITPR1 | c.7936G>A p.V2646I (on ENST00000354582; = p.V2591I on NM_002222.7) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs568805900, COSV56999999; called by muse, mutect2, varscan2
- ITPR2 | c.6097C>T p.R2033* | Nonsense Mutation (SNP) | VAF 38/165 reads (23%) | catalogued as rs1427078840, COSV101190298; called by muse, mutect2, varscan2
- ITSN1 | c.1351C>T p.R451W | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs757736852, COSV101180508; called by muse, mutect2, varscan2
- JAK1 | c.1847_1849del p.K616del | In Frame Del (DEL) | VAF 44/228 reads (19%) | catalogued as rs1339036568; called by pindel, varscan2
- JAK1 | c.1016del p.N339Ifs*3 | Frame Shift Del (DEL) | VAF 34/83 reads (41%) | catalogued as rs1181132297; called by mutect2, pindel, varscan2
- JMJD1C | c.6075del p.E2026Kfs*45 | Frame Shift Del (DEL) | VAF 85/234 reads (36%) | catalogued as rs1226801045; called by mutect2, varscan2
- JMJD7-PLA2G4B | c.2170C>T p.R724C | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as rs140808455; called by muse, mutect2, varscan2
- JPH2 | c.1170G>A p.R390= | Splice Region (SNP) | VAF 16/234 reads (7%) | catalogued as COSV100881809; called by muse, mutect2
- JPH2 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.833); catalogued as COSV65902947, COSV65905090; called by muse, mutect2, varscan2
- KANSL1 | c.3182G>A p.R1061H (on ENST00000574590 / NM_001193465.2; = p.R1062H on NM_015443.4) | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs768018906, COSV99291590; ClinVar: likely benign; called by muse, mutect2, varscan2
- KAT2A | c.1968T>A p.N656K | Missense Mutation (SNP) | VAF 132/425 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99288612; called by muse, mutect2, varscan2
- KAT5 | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV100383789, COSV100384108; called by muse, mutect2, varscan2
- KAT6B | c.1817G>A p.W606* | Nonsense Mutation (SNP) | VAF 65/174 reads (37%) | catalogued as COSV99769354; called by muse, mutect2, varscan2
- KATNAL2 | c.1003G>A p.V335I (on ENST00000356157 / NM_001353899.1; = p.V263I on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.533); catalogued as rs200886050; called by muse, mutect2, varscan2
- KBTBD2 | c.1615C>T p.R539* | Nonsense Mutation (SNP) | VAF 130/328 reads (40%) | catalogued as COSV100406622; called by muse, mutect2, varscan2
- KCNAB2 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.415); catalogued as rs777718700, COSV99379699; called by muse, mutect2
- KCND2 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 77/161 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs1272908967, COSV58579529, COSV58598715; called by muse, mutect2, varscan2
- KCNH8 | c.357A>C p.E119D | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs371170145; called by muse, mutect2, varscan2
- KCNJ8 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 112/201 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV53716189; called by muse, varscan2
- KCNQ3 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1198584017, COSV101195742; called by muse, mutect2, varscan2
- KCNS3 | c.520A>T p.R174* | Nonsense Mutation (SNP) | VAF 36/69 reads (52%) | catalogued as COSV100411574, COSV58408064; called by muse, mutect2, varscan2
- KCNS3 | c.521G>T p.R174I | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0.019); catalogued as COSV58406997; called by muse, mutect2, varscan2
- KCNS3 | c.623C>T p.S208L | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs368555119; called by muse, varscan2
- KCNV2 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as COSV101172663; called by muse, mutect2, varscan2
- KDM2B | c.3017G>A p.R1006Q | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as rs782721641, COSV65640411; called by muse, mutect2
- KDM3A | c.1958G>A p.R653Q | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs748898231, COSV100461152; called by muse, mutect2, varscan2
- KDM3B | c.3950del p.P1317Rfs*10 | Frame Shift Del (DEL) | VAF 24/125 reads (19%) | catalogued as rs1561792565; called by mutect2, pindel, varscan2
- KDM4B | c.958G>A p.V320M | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs749807599, COSV99347704; called by muse, mutect2, varscan2
- KDM4D | c.1033G>A p.V345M | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as COSV100624404; called by muse, mutect2, varscan2
- KDM5A | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 54/200 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs749556390, COSV101239107; called by muse, varscan2
- KDM5B | c.1936G>A p.V646I | Missense Mutation (SNP) | VAF 66/221 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.333); catalogued as rs769638696, COSV99351639; called by muse, mutect2, varscan2
- KIAA0319 | c.163G>A p.V55I | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.039); catalogued as rs552512704, COSV100985873; called by muse, mutect2, varscan2
- KIF15 | c.2530C>T p.L844F | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.06); catalogued as rs764788641, COSV100393423; called by muse, mutect2, varscan2
- KIF16B | c.3807G>T p.R1269S | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100735031; called by muse, mutect2, varscan2
- KIF1B | c.1943C>A p.P648H (on ENST00000377086 / NM_001365952.1; = p.P602H on NM_015074.3) | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs771169398, COSV99824468; called by muse, mutect2, varscan2
- KIF26B | c.2620G>A p.A874T | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs1558269736, COSV100833669; called by muse, varscan2
- KIF27 | c.2818C>T p.Q940* | Nonsense Mutation (SNP) | VAF 28/160 reads (18%) | catalogued as COSV99927377; called by muse, varscan2
- KIF3C | c.1834G>A p.V612M | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.673); catalogued as COSV53099579; called by muse, mutect2, varscan2
- KIF5A | c.2152C>T p.R718W | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769871370, COSV54058041; called by muse, mutect2, varscan2
- KIF5A | c.2404G>A p.V802I | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.348); catalogued as COSV99672527; called by muse, mutect2, varscan2
- KIFAP3 | c.938A>G p.D313G | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.652); catalogued as COSV63038255; called by muse, mutect2
- KIFC3 | c.2141G>A p.R714H | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs1174862009, COSV65549463, COSV65552367; called by muse, mutect2, varscan2
- KIRREL2 | c.1953del p.C652Afs*79 | Frame Shift Del (DEL) | VAF 37/200 reads (19%) | catalogued as rs761116739, COSV52880030; called by mutect2, pindel, varscan2
- KITLG | c.351A>C p.E117D | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99933640; called by muse, mutect2, varscan2
- KLC2 | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs200554250, COSV100270917; called by muse, mutect2, varscan2
- KLF4 | c.271C>A p.L91I | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.233); catalogued as COSV101012793, COSV65928750; called by muse, mutect2, varscan2
- KLHL1 | c.1915G>T p.G639C | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.847); catalogued as COSV100918407; called by muse, mutect2, varscan2
- KLHL40 | c.1087G>A p.V363M | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs368731768; called by muse, mutect2, varscan2
- KMT2C | c.5158C>T p.Q1720* | Nonsense Mutation (SNP) | VAF 224/537 reads (42%) | catalogued as COSV100078268; called by muse, mutect2, varscan2
- KMT2C | c.4122T>A p.D1374E | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100078275; called by muse, mutect2, varscan2
- KMT2C | c.2345C>A p.S782Y | Missense Mutation (SNP) | VAF 17/349 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as COSV100078277; called by muse, mutect2
- KPNA3 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT tolerated (1); PolyPhen possibly damaging (0.562); catalogued as COSV99904450; called by muse, mutect2, varscan2
- KRT7 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.206); catalogued as rs370849999; called by muse, mutect2, varscan2
- LAIR1 | c.839C>T p.T280M | Missense Mutation (SNP) | VAF 90/266 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.11); catalogued as rs770103913, COSV100479985; called by muse, mutect2, varscan2
- LAMA1 | c.6229C>G p.Q2077E | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.264); catalogued as COSV101058067; called by muse, mutect2, varscan2
- LAMA5 | c.9851G>A p.G3284D | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV99442926; called by muse, mutect2, varscan2
- LAMB2 | c.2870G>A p.R957Q | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs764846938, COSV59731562; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMB4 | c.26del p.L9Cfs*43 | Frame Shift Del (DEL) | VAF 38/102 reads (37%) | catalogued as rs747409331; called by mutect2, pindel, varscan2
- LAMC3 | c.2336dup p.Q781Pfs*7 | Frame Shift Ins (INS) | VAF 9/41 reads (22%) | catalogued as rs765163533; called by mutect2, pindel, varscan2
- LARGE1 | c.1340G>A p.R447Q | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as rs139603473; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LCE1B | c.155G>A p.C52Y | Missense Mutation (SNP) | VAF 28/287 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.648); catalogued as rs1343454518, COSV100780325; called by muse, mutect2, varscan2
- LCE3D | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 162/251 reads (65%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs775921101, COSV64230771; called by muse, mutect2, varscan2
- LEPR | c.1717C>T p.R573C | Missense Mutation (SNP) | VAF 61/118 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs748855258, COSV60754874; called by muse, mutect2, varscan2
- LGSN | c.1237A>G p.T413A | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT tolerated (0.94); PolyPhen benign (0.023); catalogued as COSV101040792; called by muse, mutect2, varscan2
- LHX4 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 188/269 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs1414975935, COSV55373031, COSV55374850; called by muse, mutect2, varscan2
- LIF | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779219330, COSV50776586; called by muse, mutect2, varscan2
- LIG3 | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs559259641, COSV99253317; called by muse, mutect2, varscan2
- LILRA5 | c.712G>T p.G238* | Nonsense Mutation (SNP) | VAF 55/143 reads (38%) | catalogued as COSV56644629; called by muse, mutect2, varscan2
- LILRB2 | c.395C>A p.P132H | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100079595, COSV58749456; called by muse, mutect2, varscan2
- LINGO2 | c.1227dup p.P410Tfs*5 | Frame Shift Ins (INS) | VAF 59/193 reads (31%) | catalogued as rs1358205090; called by mutect2, pindel, varscan2
- LIPF | c.210T>A p.N70K | Missense Mutation (SNP) | VAF 44/69 reads (64%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.583); catalogued as COSV99490694; called by muse, mutect2, varscan2
- LMBRD1 | c.868G>A p.A290T (on ENST00000649011; = p.A268T on NM_018368.4) | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as rs143758103, COSV65299886; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LMNA | c.1892dup p.S632Qfs*72 | Frame Shift Ins (INS) | VAF 5/39 reads (13%) | catalogued as rs770335541; called by mutect2, pindel, varscan2
- LOXL2 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 84/209 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.198); catalogued as rs369286803, COSV101208002; called by muse, mutect2, varscan2
- LPA | c.5844T>C p.G1948= | Splice Region (SNP) | VAF 21/75 reads (28%) | catalogued as rs769212651, COSV100308345; called by muse, mutect2, varscan2
- LRBA | c.6587G>A p.R2196H | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs760622773, COSV63958248; called by muse, mutect2, varscan2
- LRBA | c.1964G>A p.R655Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs542115160, COSV100842208; called by muse, mutect2, varscan2
- LRIG2 | c.2984G>A p.R995Q | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.03); catalogued as rs139029257, COSV100743791; called by muse, mutect2
- LRIT1 | c.52del p.Q18Rfs*26 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as rs759958964; called by mutect2, pindel, varscan2
- LRP11 | c.1157C>A p.T386N | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.172); catalogued as COSV99497943; called by muse, mutect2, varscan2
- LRP5 | c.2245G>A p.G749R | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1206599136, COSV53717882, COSV99591073; called by muse, mutect2, varscan2
- LRP5 | c.3004C>T p.R1002* | Nonsense Mutation (SNP) | VAF 10/49 reads (20%) | catalogued as rs1565094961, CM122419, COSV99592843; called by muse, mutect2, varscan2
- LRP5 | c.4730C>A p.P1577H | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99592845; called by muse, mutect2, varscan2
- LRRC27 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs768600145, COSV100690017; called by muse, mutect2, varscan2
- LRRC75B | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 66/123 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1436122244, COSV50641125, COSV99959017; called by muse, mutect2, varscan2
- LRRCC1 | c.1891G>A p.V631M | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs763467096, COSV64484642; called by muse, mutect2, varscan2
- LRRIQ3 | c.414del p.G139Dfs*20 | Frame Shift Del (DEL) | VAF 17/71 reads (24%) | catalogued as rs749244073; called by mutect2, pindel, varscan2
- LRRN2 | c.1883G>A p.R628H | Missense Mutation (SNP) | VAF 79/104 reads (76%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs142606457; called by muse, mutect2
- LRTM1 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs142542421; called by muse, mutect2, varscan2
- LSM10 | c.356dup p.N121Kfs*3 | Frame Shift Ins (INS) | VAF 45/124 reads (36%) | catalogued as COSV100240006; called by mutect2, pindel, varscan2
- LTBP1 | c.1195C>T p.R399* (on ENST00000404816 / NM_206943.4; = p.R73* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | catalogued as COSV100618105; called by muse, mutect2
- LVRN | c.899C>T p.T300M | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs762126747, COSV63496384; called by muse, mutect2, varscan2
- LY6G5C | c.529G>A p.V177I (on ENST00000375863; = p.V102I on NM_025262.3) | Missense Mutation (SNP) | VAF 142/213 reads (67%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.062); catalogued as rs758150534, COSV101020870; called by muse, mutect2, varscan2
- LYPD6B | c.23G>A p.R8H (on ENST00000409029 / NM_001317004.1; = p.R32H on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/201 reads (42%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.123); catalogued as rs773641775, COSV99700576; called by muse, mutect2, varscan2
- LYST | c.10415A>G p.Y3472C | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101090518; called by muse, mutect2, varscan2
- LZTR1 | c.2263C>T p.R755W | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141161152; called by muse, mutect2, varscan2
- MACF1 | c.10484G>A p.R3495Q | Missense Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as rs372772844; called by muse, mutect2
- MAN2B1 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as rs779091097, COSV99667469; called by muse, mutect2, varscan2
- MAP3K12 | c.991G>A p.V331M | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.835); catalogued as rs1208561631, COSV57233177; called by muse, mutect2, varscan2
- MAP3K4 | c.1670C>T p.A557V | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV100815760; called by muse, mutect2, varscan2
- MAP3K9 | c.1714A>C p.T572P | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); catalogued as COSV101173808; called by muse, mutect2, varscan2
- MAP3K9 | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 74/99 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs775951489, COSV101173809; called by muse, mutect2, varscan2
- MAP3K9 | c.1547A>C p.N516T | Missense Mutation (SNP) | VAF 43/217 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV101173811; called by muse, mutect2, varscan2
- MAPK7 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1248980248, COSV55191742; called by muse, mutect2, varscan2
- MAPK8 | c.334G>T p.D112Y | Missense Mutation (SNP) | VAF 75/233 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100827594; called by muse, mutect2, varscan2
- MAPKAPK3 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 63/311 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs759497061, COSV100781800, COSV63596839; called by muse, mutect2, varscan2
- MAPKBP1 | c.3727C>T p.R1243W (on ENST00000456763 / NM_001128608.2; = p.R1237W on NM_014994.3) | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as rs757310245, COSV52958601; called by muse, mutect2, varscan2
- MARCHF6 | c.37C>T p.R13W | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56887449; called by muse, mutect2, varscan2
- MARCHF7 | c.301A>G p.T101A | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs558685209, COSV99374224; called by muse, mutect2
- MARS2 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 43/247 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as rs1318698189, COSV99986738; called by muse, mutect2, varscan2
- MAST2 | c.2942G>A p.R981Q | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as rs202188596; called by muse, mutect2, varscan2
- MAT1A | c.1130A>G p.Y377C | Missense Mutation (SNP) | VAF 38/328 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100944508; called by muse, mutect2, varscan2
- MBD2 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.273); catalogued as rs201919549; called by muse, mutect2, varscan2
- MBD2 | c.471del p.G158Dfs*7 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | catalogued as rs755716804, COSV56502366; called by mutect2, pindel, varscan2
- MBD4 | c.939del p.E314Kfs*4 | Frame Shift Del (DEL) | VAF 96/159 reads (60%) | catalogued as rs558765093; called by mutect2, varscan2
- MBD6 | c.2345del p.G782Efs*13 | Frame Shift Del (DEL) | VAF 34/109 reads (31%) | catalogued as rs746267361; called by mutect2, varscan2
- MBNL2 | c.845A>G p.Q282R | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.112); catalogued as COSV100600591; called by muse, mutect2, varscan2
- MCM10 | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as COSV101098588; called by muse, mutect2, varscan2
- MCM3AP | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52441417; called by muse, mutect2, varscan2
- MCRS1 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.561); catalogued as rs768565145, COSV100657466; called by muse, mutect2, varscan2
- MDM2 | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 65/207 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.746); catalogued as rs755256189, COSV50698395; called by muse, mutect2, varscan2
- MDN1 | c.14800G>A p.E4934K | Missense Mutation (SNP) | VAF 73/316 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.269); catalogued as COSV65524226; called by muse, mutect2, varscan2
- MED23 | c.3116C>T p.P1039L | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.269); catalogued as rs376944115; called by muse, mutect2, varscan2
- MEGF8 | c.497del p.G166Vfs*53 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | catalogued as rs762115034; called by mutect2, pindel, varscan2
- MEPCE | c.434del p.G145Afs*11 | Frame Shift Del (DEL) | VAF 10/14 reads (71%) | catalogued as rs760012501; called by mutect2, varscan2
- MESD | c.575G>A p.G192D | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99930925; called by muse, mutect2, varscan2
- METTL22 | c.1021A>G p.T341A | Missense Mutation (SNP) | VAF 107/726 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99371992; called by muse, mutect2, varscan2
- METTL2A | c.856G>A p.G286R | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776701783, COSV100274363; called by muse, mutect2, varscan2
- METTL3 | c.1261G>A p.V421I | Missense Mutation (SNP) | VAF 104/149 reads (70%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as rs200084133, COSV52969076; called by muse, mutect2, varscan2
- MFSD5 | c.982A>G p.M328V | Missense Mutation (SNP) | VAF 95/235 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1451933704, COSV100289199; called by muse, mutect2, varscan2
- MFSD6L | c.1340A>G p.Y447C | Missense Mutation (SNP) | VAF 98/272 reads (36%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV100266728; called by muse, mutect2, varscan2
- MICALL2 | c.2617C>T p.R873W | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs769993258, COSV52515632; called by muse, mutect2, varscan2
- MIF4GD | c.419_422del p.D140Vfs*2 (on ENST00000325102 / NM_001370592.1; = p.D174Vfs*2 on NM_020679.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 40/115 reads (35%) | catalogued as rs760387965; called by mutect2, pindel, varscan2
- MIS18BP1 | c.471del p.K157Nfs*24 | Frame Shift Del (DEL) | VAF 62/123 reads (50%) | catalogued as rs546807245; called by mutect2, varscan2
- MISP | c.940C>T p.R314W | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as rs779108254, COSV53120357; called by muse, mutect2, varscan2
- MKI67 | c.2096T>A p.V699E | Missense Mutation (SNP) | VAF 91/129 reads (71%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV100897099; called by muse, mutect2, varscan2
- MMP10 | c.344A>G p.Y115C | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54246210, COSV99666844; called by muse, mutect2, varscan2
- MMP17 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs897166281, COSV62179173; called by muse, mutect2, varscan2
- MPHOSPH8 | c.314A>G p.E105G | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV100825248; called by muse, mutect2, varscan2
- MPZL2 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 83/411 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs755861299, COSV99635364; called by muse, mutect2, varscan2
- MRI1 | c.988del p.H330Tfs*24 (on ENST00000040663 / NM_001031727.4; = p.H283Tfs*24 on NM_032285.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 47/94 reads (50%) | catalogued as rs751646149; called by mutect2, pindel, varscan2
- MRPL45 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as rs550031536; called by muse, mutect2, varscan2
- MRPS14 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 57/340 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1323041289, COSV100871578; called by muse, mutect2, varscan2
- MSI1 | c.980C>T p.S327L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV99981761; called by muse, mutect2, varscan2
- MSL1 | c.971G>A p.R324Q (on ENST00000398532 / NM_001365919.1; = p.R61Q on NM_001012241.2) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.947); catalogued as rs541159266, COSV100278232; called by muse, mutect2, varscan2
- MTBP | c.701A>G p.D234G | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV100012701; called by muse, mutect2, varscan2
- MTF2 | c.1188del p.G397Efs*6 | Frame Shift Del (DEL) | VAF 30/58 reads (52%) | catalogued as rs759847587; called by mutect2, varscan2
- MTHFSD | c.1097G>A p.R366H (on ENST00000360900 / NM_001159377.2; = p.R365H on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs372334535, COSV59804603; called by muse, mutect2, varscan2
- MTMR4 | c.3071G>T p.R1024M | Missense Mutation (SNP) | VAF 37/211 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100051581; called by muse, mutect2, varscan2
- MTRR | c.299T>G p.V100G (on ENST00000264668; = p.V73G on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/220 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99242215; called by muse, mutect2, varscan2
- MUC16 | c.36743G>A p.R12248H | Missense Mutation (SNP) | VAF 109/186 reads (59%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs75003158, COSV101202278; called by muse, mutect2, varscan2
- MUC16 | c.21221T>A p.L7074H | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.068); catalogued as COSV101202280; called by muse, mutect2, varscan2
- MUSK | c.2287G>A p.A763T | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199507468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUTYH | c.899A>G p.E300G | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100588249; called by muse, mutect2, varscan2
- MYBBP1A | c.1577C>T p.T526M | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as rs371564259; called by muse, mutect2, varscan2
- MYBPC2 | c.1936C>T p.R646C | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs764900042, COSV63098901; called by muse, mutect2, varscan2
- MYCBP2 | c.2689C>T p.R897* (on ENST00000357337; = p.R935* on NM_015057.5) | Nonsense Mutation (SNP) | VAF 46/99 reads (46%) | catalogued as COSV62018819; called by muse, mutect2, varscan2
- MYH3 | c.4682G>A p.R1561Q | Missense Mutation (SNP) | VAF 124/385 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as rs756126166, COSV56863270; called by muse, mutect2, varscan2
- MYH3 | c.3997G>A p.A1333T | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as rs200734527, COSV56863991, COSV56865662; called by muse, mutect2, varscan2
- MYLIP | c.1003G>A p.V335I | Missense Mutation (SNP) | VAF 40/381 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs201087709; called by muse, mutect2, varscan2
- MYLK | c.4700G>A p.R1567Q | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as rs757766496, COSV60608475; called by muse, mutect2, varscan2
- MYO10 | c.4852C>T p.P1618S | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.303); catalogued as COSV99946621; called by muse, mutect2, varscan2
- MYO15A | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs1248557646, COSV52760772, COSV52769060; called by muse, mutect2, varscan2
- MYO18A | c.5507C>T p.T1836M | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs200336680; called by muse, mutect2, varscan2
- MYO1C | c.1741A>T p.I581F (on ENST00000648651 / NM_001080779.2; = p.I546F on NM_033375.5) | Missense Mutation (SNP) | VAF 48/330 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100704614; called by muse, mutect2, varscan2
- MYO1G | c.2080C>T p.R694C | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs576689841, COSV51857463; called by muse, mutect2, varscan2
- MYO9A | c.7427G>A p.G2476D | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.038); catalogued as COSV100614669; called by muse, mutect2, varscan2
- MYOF | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.189); catalogued as rs974756123, COSV100826238; called by muse, mutect2, varscan2
- MYOM2 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs760392633, COSV100038721; called by muse, mutect2, varscan2
- MYOM3 | c.3614C>T p.T1205M | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs370058913; called by muse, mutect2, varscan2
- MYOM3 | c.1793C>T p.P598L | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs758030227, COSV100294103; called by muse, mutect2, varscan2
- MZT2B | c.440G>A p.G147D | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs1409109943, COSV56059262, COSV99919976; called by muse, mutect2, varscan2
- NAA25 | c.241T>G p.S81A | Missense Mutation (SNP) | VAF 93/219 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV99928185; called by muse, mutect2, varscan2
- NAB2 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763299566, COSV100272844; called by muse, mutect2, varscan2
- NACC1 | c.49C>A p.L17M | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99457385; called by muse, mutect2, varscan2
1,425 further variants in this file (868 protein-altering or splice-affecting, 514 silent, 43 other) are not listed here.
